Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3494, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3494-01A (Primary Tumor).

Diagnosis / Diagnoses:

22-cm-long resection of the colon under inclusion of a moderately differentiated, centrally ulcerated adenocarcinoma, of a maximum of 3.5 cm in diameter and of the colorectal type, with a recent onset of infiltration of the pericolic fatty tissue (pT3; G2), as well as a further poorly differentiated, centrally ulcerated colorectal adenocarcinoma, of a maximum of 1 cm in diameter and with infiltration of the tunica submucosa (pT1; G3). Low-grade, also focal high-grade dysplasia (synonym: high-grade intra-epithelial neoplasia) in the remainder. Tumor-free resection margins of the colon.

A follow-up report will be made on the lymph node status.

Follow-up report:

A total of 39 histologically carcinoma-free lymph nodes of a maximum of 0.8 cm in diameter were determined after acetone fixation.

Final tumor stage: pT3 (2) pNX (0/39) pMX; G2-3

Source: NCI Genomic Data Commons file e1245baa-b205-4855-bee5-d76372d4d504 (TCGA-AA-3494.EE6B348B-B4C2-41D3-923D-741C30766ED9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).